Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7233, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7233-01A (Primary Tumor).

[page 1 of 2]
☒ Surgical Pathology

DEPARTMENT OF PATHOLOGY

PATIENT: [REDACTED] SPECIMEN [REDACTED]

BIRTHDATE: [REDACTED] AGE: [REDACTED] SEX: [REDACTED]

MRN: [REDACTED] Rm #: [REDACTED] PHYSICIAN: [REDACTED]

PROCEDURE DATE: [REDACTED] RECEIVED DATE: [REDACTED] REPORT DATE: [REDACTED]

COPY TO: [REDACTED]

Pre-Op Diagnosis

Prostate cancer

Post-Op Diagnosis

Same

Clinical History

Nothing indicated on requisition

Gross Description:

Two parts

Container labeled "[REDACTED] 1 - prostate" is a previously inked previously sectioned moderately distorted prostate gland with attached bilateral seminal vesicle weighing as received 38 grams. On reconstruction the prostate gland measures approximately 4.8 x 4.0 x 3.8 cm and has a shaggy capsule. The urethra appears to be patent with evidence of compression by the lateral lobes. The cut surface is multi-nodular rubbery tan gray. Noted in the anterior aspect at a point within 0.2 cm of the left apical (distal) margin is a poorly defined partially sectioned approximately 1.5 x 1.0 x 0.8 cm area of tan yellow slightly chalky discoloration which extends to the inked surfaces; however, this does not grossly appear to be transected at the inked surfaces. This is noted in the left lateral lobe in this area and does not grossly appear to extend to the right lateral or left posterior lobes. The seminal vesicles together are 6.8 x 2.0 x 1.0 cm with lobular outer surfaces with multi-cystic gray tan to pink fibrotic cut surface. No gross lesions are identified.

Also received in the same container are three tissue cassettes each labeled "[REDACTED] Representative sections are submitted as labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical (proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J - left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe proximal region; O - right

[page 2 of 2]
posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle.

Container labeled "[REDACTED] 2 - bilateral pelvic lymph nodes with clip on left lymph node" are two portions of tan yellow fibroadipose tissue. One portion measures 6.0 x 2.0 x 1.0 cm and has a white plastic surgical clip which is designated as from the left side. On sectioning this has a poorly defined approximately 4.6 cm elongated pink yellow nodular region with a grossly fatty cut surface. The second portion of adipose tissue is 4.6 x 3.0 x 1.1 cm and on palpation and sectioning has a 3.2 cm elongated pink yellow nodule with a fleshy tan pink cut surface. The nodule noted from the left side is sectioned and submitted labeled "A and B" while the nodule from the second portion is sectioned and submitted labeled "C and D."

Final Diagnosis

Prostate, radical prostatectomy:

Tumor characteristics:

Histologic type: Prostatic adenocarcinoma.

Gleason grade:

Primary pattern: 4

Secondary pattern: 3

Total score: 7/10

Tumor involves: Left lobe only.

Seminal vesicle involvement: Absent.

Extracapsular extension of tumor: Present left lobe distal lateral section (1D).

Lymphovascular space invasion: No.

Perineural space invasion: Yes.

High grade PIN: Absent.

Surgical margin status:

Bladder neck: Negative.

Apical (inferior): Negative.

Inked prostatic margin: Positive, left lateral (slide D1).

Lymph node status: See specimen #2.

pTN stage: pT2N0

Bilateral pelvic lymph nodes:

Lymph node designated as left: Negative for tumor.

Lymph node designated as right: Negative for tumor. PAS 9 SPC-A

CPT: 88309, 88307

Comments

This test has been finalized at the [REDACTED]

<Sign Out Dr. Signature>

[REDACTED] M.D.

Source: NCI Genomic Data Commons file d8b5a3d1-4452-40cd-a53e-91d3af19a677 (TCGA-HC-7233.3531E095-4042-4FC8-AA69-522B16E4E1FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).